MMRF case MMRF_2115 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/79a3389c-279b-4589-aadc-4900c3e7638c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Dead; Days to death: 21 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.4 years (24,236 days); ISS stage: II; Days to last known disease status: 21 days; Days to last follow up: 21 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 21 days.

Follow-up (2 entries)
- Days to follow up: -10 days; ECOG performance status: 2.
- Follow-up contact recording only the day: day 21.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Glucose 4.9 mmol/L.
- Beta 2 Microglobulin 4.5 µg/mL.
- Leukocytes 5.7 ×10⁹/L.
- Hemoglobin 8 mmol/L.
- Creatinine 97.2 µmol/L.
- Total Protein 10.2 g/dL.
- Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL.
- Serum Free Immunoglobulin Light Chain, Kappa 5.32 mg/dL.
- Blood Urea Nitrogen 8.57 mmol/L.
- Albumin 42 g/L.
- Lactate Dehydrogenase 2.72 µkat/L.
- Calcium 2.55 mmol/L.
- M Protein 3.7 g/dL.
- Platelets 186 ×10⁹/L.
- Absolute Neutrophil 2.9 ×10⁹/L.

Other clinical attributes
- Day -10: Weight: 94 kg; Height: 185 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2115_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -10 days.
- Sample MMRF_2115_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -10 days.
